TCGA case TCGA-62-8395 — Lung Adenocarcinoma (TCGA-LUAD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Bronchus and lung; Tissue source site: Thoraxklinik at University Hospital Heidelberg. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/5c266025-e590-457c-af86-4c2dc9797267

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: Germany; Age at index: 80 years; Vital status: Alive.

Diagnoses (3)
1. Adenocarcinoma with mixed subtypes (the primary disease): ICD-O-3 morphology code: 8255/3; ICD-10 code: C34.1; Tissue or organ of origin: Upper lobe, lung; Site of resection or biopsy: Lung, NOS; Laterality: Right; Classification of tumor: primary; Age at diagnosis: 80.2 years (29,311 days); Year of diagnosis: 2009; AJCC staging edition: 6th; AJCC pathologic T: T3; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIB; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0; Sites of involvement: Central Lung.
   Pathology details: Consistent pathology review: Yes.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS; adjuvant Radiation Therapy, NOS.
2. Recurrence of diagnosis 1 (Adenocarcinoma with mixed subtypes). Age at diagnosis: 81.3 years (29,706 days); Days to diagnosis: 395 days (1.1 years); Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Recurrent Disease.
   Recorded as not given: Radiation Therapy, NOS, for recurrent disease; Surgery, NOS to Locoregional Site.
3. Recurrence of diagnosis 1 (Adenocarcinoma with mixed subtypes). Age at diagnosis: 81.6 years (29,811 days); Days to diagnosis: 500 days (1.4 years); Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Recurrent Disease.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Progressive Disease.
   Recorded as not given: Radiation Therapy, NOS, for recurrent disease; Radiation Therapy, NOS, for progressive disease; Surgery, NOS to Locoregional Site; Surgery, NOS to Distant Site.

Follow-up (6 entries)
- Day 395 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Days to recurrence: 395 days (1.1 years); Evidence of recurrence type: Convincing Image Source.
- Day 500 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Days to recurrence: 500 days (1.4 years); Evidence of progression type: Convincing Image Source.
- Day 500 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Days to progression: 500 days (1.4 years); Evidence of progression type: Convincing Image Source.
- Days to follow up: 705 days (1.9 years); Disease response: With Tumor.
- Days to follow up: 1,216 days (3.3 years); Disease response: With Tumor.
- Karnofsky performance status: 100; ECOG performance status: 0; Timepoint: Preoperative.

Other clinical attributes
- FEV1/FVC before bronchodilator (%): 86; FEV1 before bronchodilator (% of reference): 130.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Lifelong Non-Smoker.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-62-8395-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Longest dimension: 1; Intermediate dimension: 0.6; Shortest dimension: 0.5.
  Slide TCGA-62-8395-01A-01-BS1: Section location: Bottom; Percent tumor cells: 96; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 1; Percent stromal cells: 3; Percent lymphocyte infiltration: 2; Percent monocyte infiltration: 3.
  Slide TCGA-62-8395-01A-01-TS1: Section location: Top; Percent tumor cells: 96; Percent tumor nuclei: 70; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 4; Percent lymphocyte infiltration: 5; Percent monocyte infiltration: 3.
- Sample TCGA-62-8395-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.
- Sample TCGA-62-8395-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Longest dimension: 1.2; Intermediate dimension: 1; Shortest dimension: 0.6.
  Slide TCGA-62-8395-11A-01-TS1: Section location: Top; Percent lymphocyte infiltration: 3; Percent monocyte infiltration: 20.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Submitted tumor site: Lung; Histologic diagnosis: Lung Adenocarcinoma Mixed Subtype; History neoadjuvant treatment: No; Prospective collection: No; Retrospective collection: Yes; Tumor status: With tumor; Tobacco smoking history indicator: 1; Anatomic organ subdivision: R-Upper; Location lung parenchyma: Central Lung; KRAS gene analysis indicator: No; EGFR mutation status: Yes; Eml4 alk translocation status: No; Pulmonary function test indicator: Yes; Treatment outcome first course: Complete Remission/Response.
- Follow-up form: Lost to follow-up: No; Treatment outcome first course: Complete Remission/Response; New tumor event surgery: No; Tumor status: With tumor; New tumor event radiation treatment: No; New tumor event pharmaceutical treatment: Yes.
- Follow-up form, New neoplasm event types: New tumor event type: Locoregional Recurrence.
- Follow-up form, Progression determined by list: New tumor event diagnosis evidence: Convincing Imaging.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 1,216 days; disease-specific survival: no event (censored), 1,216 days; disease-free interval: event (new tumor event after initially disease-free), 395 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 395 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-62-8395-01A-11D-2322-01): tumor purity 0.65, ploidy 1.9, whole-genome doublings 0.
